Somatic mutation profile of tumor specimen TCGA-2Z-A9JN-01A (aliquot TCGA-2Z-A9JN-01A-21D-A42J-10) from TCGA case TCGA-2Z-A9JN, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 50.0 years (18,264 days).
Specimen TCGA-2Z-A9JN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76e1810d-a416-4395-a70f-1efde1858bc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JN-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JN-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06280e1d-8cfb-4a1e-8255-16dfdfc888dd

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 41/117 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTB | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.402); catalogued as COSV59318330; called by muse, mutect2, varscan2
- CD1A | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as rs769686492, COSV56860291; called by muse, mutect2, varscan2
- CDH8 | c.1948G>T p.E650* | Nonsense Mutation (SNP) | VAF 12/148 reads (8%) | catalogued as COSV100180835, COSV54898931; called by muse, mutect2
- DLK2 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99767051; called by muse, mutect2, varscan2
- DNAH8 | c.4673T>C p.L1558S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544353; called by muse, mutect2, varscan2
- FLNC | c.6052C>T p.R2018C | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs1335627502, COSV100367922, COSV57952809; ClinVar: uncertain significance; called by muse, varscan2
- NDRG1 | c.1048A>C p.T350P | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100105878; called by muse, mutect2, varscan2
- PTPRR | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99317029; called by muse, mutect2, varscan2
- SEC24A | c.953C>G p.P318R | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100524435; called by muse, mutect2, varscan2
- SNX19 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs779185353, COSV99772963, COSV99773586; called by muse, mutect2, varscan2
- HSPH1 | c.1293del p.L432Sfs*4 | Frame Shift Del (DEL) | VAF 25/164 reads (15%) | called by mutect2, pindel, varscan2
- ARRDC1 | c.363C>G p.S121= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs1450440267, COSV101004528; called by muse, mutect2, varscan2
- MIGA2 | c.1560C>G p.V520= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99477517; called by muse, mutect2, varscan2
- PPP1R3B | c.240G>A p.S80= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs758184308, COSV100133908; called by muse, mutect2, varscan2
- SIPA1L3 | c.2076C>T p.Y692= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs187615405; called by muse, mutect2, varscan2
- TAS1R2 | c.504C>T p.S168= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs373438774; called by muse, mutect2, varscan2
- ZNF536 | c.1368C>T p.G456= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs756832106, COSV62829626; called by muse, mutect2, varscan2
